Somatic mutation profile of tumor specimen MMRF_1603_1_BM_CD138pos (aliquot MMRF_1603_1_BM_CD138pos_T1_KBS5U_L03480) from MMRF case MMRF_1603, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.7 years (25,840 days).
Specimen MMRF_1603_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 370e5ff5-d337-409e-a631-1060bb8aaeb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1603_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1603_1_PB_Whole_C4_KBS5U_L03492; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21515ebf-bec4-46f6-a65d-194c8ac5f073

The open-access MAF lists 132 somatic variants for this specimen: 41 protein-altering or splice-affecting, 15 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 37, Missense Mutation 36, Intron 22, Silent 15, 3'Flank 7, 5'UTR 6, RNA 2, 5'Flank 2, Translation Start Site 1, Nonsense Mutation 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 66/201 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463057954, CM081494, COSV55591183; called by mutect2, varscan2
- BRINP3 | c.1818G>T p.Q606H | Missense Mutation (SNP) | VAF 119/204 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1471961126, COSV66523813; called by muse, mutect2, varscan2
- C1orf94 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 59/171 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1420837131; called by muse, mutect2, varscan2
- CDH23 | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 136/265 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368496658, COSV54924985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHID1 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203610916; called by muse, mutect2
- CNNM1 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63201399, COSV63201751; called by muse, mutect2, varscan2
- CREBBP | c.4001T>C p.L1334P | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM085343, COSV52117897; called by muse, mutect2, varscan2
- CYP27C1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 83/115 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780153463; called by muse, mutect2, varscan2
- ELOA | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69311463; called by muse, mutect2
- FASLG | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs773045347; called by muse, varscan2
- GSDMD | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs772265737, COSV52796435; called by muse, mutect2, varscan2
- H2AC15 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV57584653, COSV57585726; called by muse, mutect2, varscan2
- IGHV2-70 | c.166A>T p.S56C | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs759335337; called by muse, varscan2
- NOC4L | c.902-4G>A | Splice Region (SNP) | VAF 7/53 reads (13%) | catalogued as rs768007892; called by muse, mutect2, varscan2
- OBSL1 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.58); PolyPhen probably damaging (1); catalogued as rs1479403958; called by muse, mutect2, varscan2
- PSAPL1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756203005, COSV59844480; called by muse, mutect2, varscan2
- SLC30A8 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs1267353057, COSV69969913; called by muse, mutect2, varscan2
- TMEM117 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861886; called by muse, mutect2
- ZNF558 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256254386, COSV56864045; called by muse, mutect2, varscan2
- ANKRD17 | c.5732C>G p.T1911S | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- C15orf39 | c.2275C>G p.P759A | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNG8 | c.159C>A p.N53K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNE1 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CPNE6 | c.148T>G p.S50A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EBF1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- FARSB | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- FCRL4 | c.163A>C p.T55P | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HECW1 | c.3235-1G>C p.X1079_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2
- HHIP | c.1995A>C p.Q665H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HS6ST3 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHA1 | c.312del p.S105Qfs*35 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, varscan2
- NAT9 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RYR3 | c.13535G>A p.R4512K (on ENST00000389232; = p.R4513K on NM_001036.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SENP7 | c.2581T>C p.W861R | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK5 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.2140G>C p.V714L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SREBF2 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SVIL | c.6284A>T p.N2095I (on ENST00000355867 / NM_021738.3; = p.N1669I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TSPAN33 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDFY3 | c.4090A>T p.T1364S | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ARSJ | c.159G>A p.E53= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs540011201; called by muse, mutect2
- BORA | c.18C>T p.F6= | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- COL6A1 | c.2733C>T p.N911= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs144585693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXG1 | c.621C>T p.I207= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs771755778; called by muse, mutect2, varscan2
- IGHV1-69D | c.183A>C p.G61= | Silent (SNP) | VAF 48/117 reads (41%) | called by muse, varscan2
- IGHV1-69D | c.69G>A p.L23= | Silent (SNP) | VAF 15/27 reads (56%) | called by mutect2, varscan2
- IGHV2-70D | c.357A>T p.I119= | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, varscan2
- METTL22 | c.246A>T p.T82= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- NCAM2 | c.1029C>T p.F343= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV53068876; called by muse, mutect2, varscan2
- NR3C1 | c.2094A>G p.G698= | Silent (SNP) | VAF 109/299 reads (36%) | called by muse, mutect2, varscan2
- PHC1 | c.1122C>A p.I374= | Silent (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- POLG | c.1785G>A p.Q595= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- SOGA1 | c.711C>T p.A237= | Silent (SNP) | VAF 50/96 reads (52%) | catalogued as rs752602939; called by muse, mutect2, varscan2
- SOGA3 | c.2259C>T p.A753= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV64106198; called by muse, mutect2
- TMEM98 | c.477G>A p.T159= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs150723262; called by muse, mutect2
- ABCG2 | c.*1411C>T | 3'UTR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- ADAM19 | chr5:157480482 G>A | 3'Flank (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- ADCY2 | c.*2733G>A | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- ADGRL3 | chr4:62071332 G>T | 3'Flank (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- AMER3 | c.*198G>A | 3'UTR (SNP) | VAF 34/143 reads (24%) | catalogued as rs904140782, COSV100366874; called by muse, mutect2, varscan2
- ARL14EP | c.-63-647C>A | Intron (SNP) | VAF 76/148 reads (51%) | called by muse, mutect2, varscan2
- ARL5A | c.*4259del | 3'UTR (DEL) | VAF 46/202 reads (23%) | called by mutect2, pindel, varscan2
- BDH1 | c.562+40C>A | Intron (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- C12orf43 | c.361+161C>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- CAMKK1 | c.*1445C>T | 3'UTR (SNP) | VAF 59/141 reads (42%) | called by muse, mutect2, varscan2
- CBL | c.*287del | 3'UTR (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CSPG4P13 | n.1177T>G | RNA (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- CTLA4 | c.*605A>T | 3'UTR (SNP) | VAF 8/8 reads (100%) | called by muse, mutect2
- CXADR | c.*4149C>T | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- DBNL | c.*1770C>T | 3'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as rs565684764; called by muse, mutect2, varscan2
- EFNB2 | c.*1448T>C | 3'UTR (SNP) | VAF 25/39 reads (64%) | called by muse, mutect2, varscan2
- EGFLAM | c.98-32086A>T | Intron (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2
- ERI1 | c.*2934_*2935del | 3'UTR (DEL) | VAF 17/53 reads (32%) | called by pindel, varscan2
- FAT3 | c.13052-617G>A | Intron (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- FBXO36 | c.*2024C>T | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- FBXW8 | chr12:117031114 C>T | 3'Flank (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- FIBIN | c.-190C>T | 5'UTR (SNP) | VAF 18/56 reads (32%) | catalogued as COSV59413296; called by muse, mutect2
- FOXP1 | c.181-17990A>G | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs750515529; called by muse, mutect2, varscan2
- GCSAM | c.*224C>T | 3'UTR (SNP) | VAF 10/94 reads (11%) | catalogued as rs1284192253; called by muse, mutect2, varscan2
- GRIA4 | c.247+944C>G | Intron (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- GTPBP1 | c.*1630G>A | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863419 C>G | 5'Flank (SNP) | VAF 10/18 reads (56%) | catalogued as rs1555384615; called by muse, varscan2
- IGHV2-70D | c.-42A>C | 5'UTR (SNP) | VAF 22/34 reads (65%) | called by muse, mutect2
- IRX2 | c.-210G>A | 5'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- JAGN1 | c.*838A>G | 3'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.2413-10066T>G | Intron (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- KLF9 | c.-716C>T | 5'UTR (SNP) | VAF 55/212 reads (26%) | called by muse, mutect2, varscan2
- LIMS1 | chr2:108685309 G>A | 3'Flank (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- LINC02272 | n.564C>T | RNA (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- LTB | c.162+89T>G | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- MACROD2 | chr20:16052995 A>T | 3'Flank (SNP) | VAF 41/78 reads (53%) | catalogued as rs1290902027; called by muse, mutect2, varscan2
- MARK3 | c.*43del | 3'UTR (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- MIR6080 | chr17:64781518 G>C | 3'Flank (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- MMP16 | c.1222+5232T>G | Intron (SNP) | VAF 31/55 reads (56%) | catalogued as COSV99687356; called by muse, mutect2, varscan2
- MTMR2 | c.*2276C>T | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- NAV2 | chr11:20119362 G>T | 3'Flank (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- NHLRC2 | c.*918A>T | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- NOL8 | c.3176-54A>T | Intron (SNP) | VAF 85/141 reads (60%) | called by muse, mutect2, varscan2
- NR2F2 | c.-425C>A | 5'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4229G>A | Intron (SNP) | VAF 22/92 reads (24%) | catalogued as rs1437192786, COSV56554740; called by muse, mutect2, varscan2
- PDZD8 | c.*3989A>C | 3'UTR (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- PIGP | c.*1601C>T | 3'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- PISD | c.322-4275G>A | Intron (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- POLR3D | c.*1493C>G | 3'UTR (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.*225C>A | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- PTER | c.*440T>C | 3'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- PTPRD | c.541+120C>T | Intron (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- RALYL | c.*707C>T | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- RBM24 | c.*70A>C | 3'UTR (SNP) | VAF 148/282 reads (52%) | called by muse, varscan2
- RBM24 | c.*167A>G | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, varscan2
- RET | c.*155G>A | 3'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- RHAG | c.641-109A>T | Intron (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- RIOK2 | c.1494+79A>G | Intron (SNP) | VAF 265/412 reads (64%) | catalogued as rs1275497090; called by muse, mutect2, varscan2
- RIPPLY2 | c.174+52A>G | Intron (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- RNF144B | c.*2779G>A | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- RORA | c.*8939T>A | 3'UTR (SNP) | VAF 40/136 reads (29%) | catalogued as rs565216799; called by muse, mutect2, varscan2
- RUNX1T1 | c.*1611T>G | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2
- S1PR3 | c.*611T>A | 3'UTR (SNP) | VAF 47/141 reads (33%) | catalogued as COSV100822482; called by muse, mutect2, varscan2
- SEZ6L | c.95-95G>C | Intron (SNP) | VAF 55/191 reads (29%) | catalogued as rs1249912207; called by muse, mutect2, varscan2
- SLC6A19 | c.1017-24C>T | Intron (SNP) | VAF 47/75 reads (63%) | catalogued as rs374366704; called by muse, mutect2, varscan2
- SPA17 | c.*2477C>A | 3'UTR (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- SPAG9 | c.590+708C>T | Intron (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- SRA1 | c.62-74T>G | Intron (SNP) | VAF 110/204 reads (54%) | called by muse, mutect2, varscan2
- STXBP5L | c.*1212A>G | 3'UTR (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- TRIO | c.*498C>A | 3'UTR (SNP) | VAF 36/52 reads (69%) | called by muse, mutect2, varscan2
- UBE2E2 | c.*368_*373del | 3'UTR (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- UBQLN4 | c.*554G>A | 3'UTR (SNP) | VAF 76/290 reads (26%) | catalogued as rs879414854; called by muse, mutect2, varscan2
- WDR19 | c.3716+34G>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs371699015; called by mutect2, varscan2
- ZBED4 | c.*1229T>C | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- ZNF215 | c.-100A>C | 5'UTR (SNP) | VAF 223/545 reads (41%) | called by muse, mutect2, varscan2
- ZNF606 | chr19:58007172 ins G | 5'Flank (INS) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
